Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3U6, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3U6-01A (Primary Tumor).

[page 1 of 3]
DEPARTMENT OF PATHOLOGY

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Physician: [REDACTED]

CC: [REDACTED]

Patient Address: [REDACTED]

Date of Receipt: [REDACTED]

Date of Report: [REDACTED]

....

Clinical Diagnosis & History:

rear old with mesenteric mass left upper quadrant.

Specimens Submitted:

- 1: Radical resection of retroperitoneal sarcoma with resection of proximal jejunum and left adrenal gland
- 2: Fourth part of duodendum

DIAGNOSIS:

1. Retroperitoneal sarcoma with resection of proximal jejunum, radical resection:
- High grade dedifferentiated liposarcoma, involving mesenteric fat.
- There are three separate tumor nodules identified grossly, measuring 8.5 x 7.5 x 8.1 cm, 8.5 x 7.5 x 4 cm and 4 x 3.5 x 2 cm respectively.
- The first mass is involving the subserosal fat of the small bowel. It shows a dedifferentiated component with a high grade malignant fibrous histiocytoma-like morphology, estimated as 30-40% of the mass.
- The second mass is composed of predominantly well-differentiated liposarcoma component.
- The third mass shows equal well-differentiated and dedifferentiated components.
- Non neoplastic small bowel is unremarkable
- Small bowel resection margins are free of tumor
2. Fourth part of duodendum, resection:
- Duodenum with acute serositis, no evidence of malignancy.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically ***

Gross Description:

- 1) The specimen is received fresh, labeled "radical resection of retroperitoneal sarcoma with resection of proximal jejunum and left adrenal

** Continued on next page **

ICD-O-3
liposarcoma, dedifferentiated
885813
site: retroperitoneum
c48.0
5-2-12 eo

[page 2 of 3]
SURGICAL

----- Page 2 of 3

gland", and consists of a coiled bowel loop of small bowel measuring 50 cm in length and 3 cm in diameter. There is attached mesentery measuring 32 cm and 16 x 5 cm. A small portion of the adrenal gland embedded in adipose tissue is identified, measuring 1.7 x 1.5 cm. There are three separate masses identified arising in the mesentery. The first mass is 8.5 x 7.5 x 8.1 cm (M1), the second mass is 8.5 x 7.5 x 4 cm (M2) and the third mass is 4 x 3.5 x 2 cm (M3). All the masses have a tan yellow -white firm cut surface and there are focal areas of hemorrhage in M1. The M1 and M2 are arising from the wall of the small bowel. The small bowel mucosa is unremarkable. The possible adrenal gland appears unremarkable and the M3 appears to be arising in the adipose tissue surrounding the gland. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

P - proximal margin, shaved

D - distal margin, shaved

M1--mass #1

M2--mass#2

M3--mass#3

RA--representative possible adrenal

2).The specimen is received fresh labeled, "fourth part of duodenum", and consists of a segment of small bowel, measuring 4.5 cm in length and 3.5 cm in diameter. The mucosa appears unremarkable. There are no gross lesions identified. The specimen is representatively submitted.

Summary of sections:

M1-margin

M2--opposite margin

U--representative of mucosa

Summary of Sections:

Part 1: Radical resection of retroperitoneal sarcoma with resection of proximal jejunum and left adrenal gland

Block	Sect.	Site	PCs
1		DM	2
7		M1	8
8		M2	9
5		M3	6
1		PM	2
2		RA	3

Part 2: Fourth part of duodendum

** Continued on next page **

[page 3 of 3]
SURGICAL

Page 3 of 3

Block	Sect.	Site	PCs
1		M1	2
1		M2	2
1		U	2

** End of Report **

Source: NCI Genomic Data Commons file b67abd26-1f87-4847-8198-7432b4a901d9 (TCGA-DX-A3U6.725CC531-F19E-401A-8450-3628049AC166.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).